MMRF case MMRF_2411 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5610ff41-96a3-4e96-b301-d4d5761d10a7

Demographics
Sex at birth: male; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.8 years (20,739 days); ISS stage: III; Days to last known disease status: 729 days (2.0 years); Days to last follow up: 729 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 129 days; Days to treatment end: 129 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 130 days; Days to treatment end: 130 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 244 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 0): M Protein 4.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 50.4 mg/dL; Immunoglobulin G 58.4 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 6.18 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.13 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.13 mmol/L; Albumin 29 g/L; Total Protein 9.3 g/dL; Glucose 9.46 mmol/L; C-Reactive Protein 1.08 mg/dL.
- Day 64 (ECOG 0): M Protein 2.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 57.4 mg/dL; Immunoglobulin G 31.8 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 1.6 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 5.74 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 28 g/L; Total Protein 8.2 g/dL; Glucose 25.7 mmol/L.
- Day 169 (ECOG 0): M Protein 0.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.65 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 4.36 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 13.1 mmol/L.
- Day 246 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.19 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 2.06 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.95 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7.4 g/dL; Glucose 8.25 mmol/L.
- Day 344 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.07 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 1.31 µg/mL; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.11 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 24.8 mmol/L.
- Day 428 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.85 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.77 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 1.89 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.06 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 22.9 mmol/L.
- Day 526 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.45 µg/mL; Hemoglobin 6.45 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.88 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 18.8 mmol/L.
- Day 645 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.84 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 2.34 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 1.93 µg/mL; Lactate Dehydrogenase 1.67 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.65 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 19.3 mmol/L.
- Day 729 (ECOG 0): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.03 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 2.03 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.77 µg/mL; Lactate Dehydrogenase 1.75 µkat/L; Hemoglobin 4.03 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.29 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 10.8 mmol/L.

Other clinical attributes
- Day -20: Weight: 81 kg; Height: 178 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2411_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2411_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
